Gene-level copy-number profile of tumor specimen TCGA-CD-5799-01A from TCGA case TCGA-CD-5799, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 45.3 years (16,533 days).
Specimen TCGA-CD-5799-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.34a55cdd-3423-420f-be43-731444cc53b6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-5799-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ddc48a53-2a25-4fc3-acc1-30a0fccba535

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 90; copy number 1: 37,741; copy number 2: 20,194; copy number 3: 1,387; copy number 4: 117; copy number 5: 10; copy number 6: 62; copy number 7: 106; copy number 8: 5; copy number 9: 55; copy number 14: 3; copy number 15: 7; copy number 20: 1; copy number 23: 15; copy number 24: 3; copy number 33: 1; copy number 38: 8; copy number 50: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CD-5799-01A-11D-1599-01): tumor purity 0.63, ploidy 3.23, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 90 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:132,836,772–133,263,115, 6 genes (within-gene range 0–1): AC115622.1, AC110751.1, AC105383.1, R3HDM2P1, PCDH10, AC108052.1.
- chr8:55,067,585–55,542,054, 4 genes (within-gene range 0–1): AC084834.1, XKR4, AC022679.2, AC022679.1.
- chr8:68,330,955–72,470,972, 57 genes: C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, AC120194.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1, EYA1, TRAPPC2P2, AC009446.1, AC104012.1, U8, MSC-AS1, MSC, RPS20P20, TRPA1, AC078906.1, AC022905.1, RNA5SP271, AC124293.1, AC011131.1.
- chr8:73,991,392–74,548,617, 13 genes: LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1, JPH1, GDAP1, AC103952.1, Y_RNA, MIR5681A, MIR5681B.
- chr8:74,603,244–74,633,320, 2 genes: PCBP2P2, AC115837.1.
- chr8:74,798,784–74,866,939, 1 gene (within-gene range 0–14): AC011632.1.
- chr8:74,824,534–75,034,558, 4 genes (within-gene range 0–14): PI15, AC011632.2, CRISPLD1, AC100782.1.
- chr8:77,399,072–77,537,290, 1 gene (within-gene range 0–4): AC062004.1.
- chr16:78,793,584–78,826,006, 2 genes: AC009141.1, RPS3P7.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 1,792 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–22,661,637, 729 genes, copy number 3 (broad region; genes not listed).
- chr1:22,719,517–22,719,598, 1 gene, copy number 3: MIR4684.
- chr7:87,151,422–99,784,248, 223 genes, copy number 3–9 (broad region; genes not listed).
- chr8:34,174,886–35,093,509, 7 genes, copy number 3: AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1, AC099685.1.
- chr8:38,543,276–40,520,158, 36 genes, copy number 3–4: AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1.
- chr8:41,261,962–43,030,535, 52 genes, copy number 3–4 (within-gene range 1–4): SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA.
- chr8:73,670,441–73,984,883, 11 genes, copy number 7 (within-gene range 2–7): AC027018.1, AC022826.2, UBE2W, AC022826.1, RN7SL760P, AC022868.1, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3.
- chr8:74,599,775–74,823,313, 1 gene, copy number 14 (within-gene range 0–14): MIR2052HG.
- chr8:74,705,693–74,705,747, 1 gene, copy number 14: MIR2052.
- chr8:74,804,287–74,804,811, 1 gene, copy number 14: AC026616.1.
- chr8:75,120,409–76,683,308, 11 genes, copy number 3–24 (within-gene range 1–26): CASC9, LINC02886, HIGD1AP6, PKMP4, HNF4G, AC011029.1, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1.
- chr10:12,877,459–16,207,927, 67 genes, copy number 3–5 (broad region; genes not listed).
- chr11:68,121,624–70,436,584, 62 genes, copy number 6 (broad region; genes not listed).
- chr11:70,477,277–70,706,068, 6 genes, copy number 3: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr17:33,111,858–33,131,743, 1 gene, copy number 33: AC008133.1.
- chr17:36,591,879–37,406,836, 18 genes, copy number 8–50 (within-gene range 1–50): DHRS11, MRM1, AC243830.2, AC243830.3, AC243830.1, LHX1-DT, LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5, ACACA, AC244093.1, HMGB1P24, AC244093.2.
- chr17:39,461,486–39,864,312, 15 genes, copy number 15–38 (within-gene range 1–38): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3.
- chr17:46,193,576–46,757,464, 15 genes, copy number 23 (within-gene range 1–23): KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1, ARL17B, LRRC37A, RN7SL656P, NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B, NSF.
- chr18:47,390–15,330,282, 376 genes, copy number 3 (broad region; genes not listed).
- chr18:21,182,503–27,795,637, 131 genes, copy number 3 (broad region; genes not listed).
- chr18:32,672,673–35,345,482, 28 genes, copy number 3: KLHL14, AC012123.1, AC012123.2, AC090371.2, CCDC178, AC090371.1, AC091198.1, ASXL3, NOL4, Y_RNA, AC104985.3, AC104985.1, AC104985.2, DTNA, AC013290.1, AC022601.1, AC068506.1, MAPRE2, AC015967.2, AC015967.1, ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1, ZNF271P, AC116447.1, ZNF24.

Autosomal genes at a single copy (total copy number 1): 35,354. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
